Somatic mutation profile of tumor specimen TCGA-V4-A9F3-01A (aliquot TCGA-V4-A9F3-01A-11D-A39W-08) from TCGA case TCGA-V4-A9F3, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 49.3 years (17,997 days).
Specimen TCGA-V4-A9F3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9636be9-19e8-47d8-84c2-a1d1d9c6092e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9F3-10A (Blood Derived Normal), aliquot TCGA-V4-A9F3-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47abc6e4-b85b-4858-88b8-831f2c48160b

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- FLNC | c.4088G>C p.G1363A | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.251); catalogued as rs750856173; called by muse, mutect2, varscan2
- PDGFRA | c.2575G>A p.V859M | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1060501520, COSV57265097; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF555 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs764653741, COSV62073279, COSV62073849; called by muse, mutect2, varscan2
- PCGF6 | c.956dup p.R320Kfs*9 (on ENST00000369847 / NM_001011663.2; = p.R245Kfs*9 on NM_032154.4) | Frame Shift Ins (INS) | VAF 28/111 reads (25%) | called by mutect2, pindel, varscan2
- RAB38 | c.334T>G p.L112V | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BPI | c.1086C>G p.T362= (on ENST00000262865; = p.T358= on NM_001725.3) | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99480796; called by muse, mutect2, varscan2
- IGSF9 | c.1458C>T p.C486= (on ENST00000368094 / NM_001135050.2; = p.C470= on NM_020789.4) | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
